Somatic mutation profile of tumor specimen TCGA-61-1995-01A (aliquot TCGA-61-1995-01A-01W-0722-08) from TCGA case TCGA-61-1995, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 43.8 years (16,016 days).
Specimen TCGA-61-1995-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 046af75d-3b8b-4b24-825f-fc717cb26d12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1995-11A (Solid Tissue Normal), aliquot TCGA-61-1995-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7716f8f6-bab0-49e1-9e41-6794527221e4

The open-access MAF lists 35 somatic variants for this specimen: 32 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 29, Silent 3, In Frame Del 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 97/156 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACKR3 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 56/590 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99799969; called by muse, mutect2
- AKAP11 | c.2645C>T p.T882M | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs753406952, COSV99214499; called by muse, mutect2, varscan2
- CDC25B | c.741G>T p.E247D (on ENST00000245960 / NM_021873.3; = p.E233D on NM_004358.4) | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.472); catalogued as COSV55655090; called by muse, mutect2, varscan2
- CEBPZ | c.760_762del p.L254del | In Frame Del (DEL) | VAF 30/127 reads (24%) | catalogued as rs757843958; called by pindel, varscan2
- CHD6 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778215281, COSV58555105; called by muse, mutect2, varscan2
- CSMD3 | c.8875G>T p.V2959L (on ENST00000297405 / NM_001363185.1; = p.V2790L on NM_052900.3) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1185360534, COSV52121321, COSV52126441; called by muse, mutect2, varscan2
- CYP2A6 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56536857; called by muse, mutect2
- EIF2AK3 | c.931A>C p.K311Q | Missense Mutation (SNP) | VAF 121/309 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57545730; called by muse, mutect2, varscan2
- FAT2 | c.9812-1G>T p.X3271_splice | Splice Site (SNP) | VAF 4/58 reads (7%) | catalogued as rs1379365273, COSV99944535; called by muse, mutect2
- FRAS1 | c.58T>A p.L20M | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.328); catalogued as COSV99356815; called by muse, mutect2
- HAS3 | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99544913; called by muse, varscan2
- HSP90AA1 | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV53487833; called by muse, mutect2, varscan2
- IFIT1 | c.126G>C p.Q42H | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1170582150, COSV100878784; called by muse, mutect2
- ITIH2 | c.113T>A p.L38Q | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV100623489; called by muse, mutect2
- KCTD12 | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.818); catalogued as COSV58524362; called by muse, mutect2, varscan2
- KMT2C | c.13117C>G p.P4373A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.777); catalogued as COSV100078420; called by muse, varscan2
- OR2G3 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 18/613 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60680733; called by muse, mutect2
- PBLD | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53265468; called by muse, mutect2, varscan2
- PCDHA13 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV56477337; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53452337; called by muse, varscan2
- PRUNE2 | c.6452G>A p.R2151Q | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780026396, COSV65038828; called by muse, mutect2, varscan2
- RBL2 | c.2314G>C p.A772P | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100044201; called by muse, mutect2
- RYR2 | c.12977A>T p.K4326I | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV100773397; called by muse, mutect2, varscan2
- SEC61A2 | c.834C>G p.S278R | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV53651140; called by muse, mutect2, varscan2
- SLC45A4 | c.1369G>A p.D457N (on ENST00000517878 / NM_001286646.2; = p.D406N on NM_001080431.2) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs756654206, COSV50134222; called by mutect2, varscan2
- TEX13A | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs922489358, COSV61146696; called by muse, mutect2, varscan2
- UBXN11 | c.1051C>T p.R351W (on ENST00000374221 / NM_183008.2; = p.R318W on NM_145345.2) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs753768406, COSV54624637; called by muse, mutect2, varscan2
- USP9X | c.5735A>G p.D1912G | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV61066991; called by muse, varscan2
- ZNF260 | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV101591080; called by muse, mutect2, varscan2
- FAM83B | c.2521del p.S841Afs*9 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, varscan2
- SYNRG | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF3C3 | c.93C>G p.R31= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV55831317; called by muse, mutect2, varscan2
- TGM7 | c.1749C>T p.R583= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs745467206, COSV71772632; called by muse, mutect2, varscan2
- ZNF548 | c.1305C>T p.N435= | Silent (SNP) | VAF 71/162 reads (44%) | catalogued as COSV60240602; called by muse, mutect2, varscan2
